CCDI case PBCNTZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Granular Cell Tumors and Alveolar Soft Part Sarcomas.
https://portal.gdc.cancer.gov/cases/53d4278c-c8a8-4828-b732-430332d4f255

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Alveolar rhabdomyosarcoma: ICD-O-3 morphology code: 8920/3; Tissue or organ of origin: Nasal cavity; Age at diagnosis: 18.1 years (6,601 days).

Biospecimens (3 samples)
- Sample 0DWNR1: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DWNSS: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DWNTN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
